Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7389, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7389-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession Number: [REDACTED] x

Final Report

DIAGNOSIS:

1) PHARYNX, LEFT SUPRAGLOTTIS, BIOPSY: INVASIVE SQUAMOUS CELL CARCINOMA
(SIMILAR TO PREVIOUS [REDACTED])

Electronically signed by: [REDACTED]
[REDACTED]

CLINICAL DATA

Clinical Features/Dx: Unspecified

Operator: Dr. [REDACTED]

Operation: [REDACTED]

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1)left supraglottis

GROSS DESCRIPTION:

1) SOURCE: Left Supraglottis

Received fresh is a fragment of tan-pink soft tissue measuring 0.4 x 0.2
x 0.1 cm. The specimen is submitted in a teabag.

Summary of sections: 1A, 1/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SNOMED: T-55000,M-74000,

Source: NCI Genomic Data Commons file 747be99a-04d9-4bcd-b820-d754a8e5b446 (TCGA-CR-7389.BB8CDA38-08EA-4237-946E-B4037267803A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).